Somatic mutation profile of tumor specimen TCGA-WX-AA47-01A (aliquot TCGA-WX-AA47-01A-11D-A38X-10) from TCGA case TCGA-WX-AA47, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 33.0 years (12,056 days).
Specimen TCGA-WX-AA47-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7c882cea-3288-4bba-837c-6b878f693c01.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WX-AA47-10A (Blood Derived Normal), aliquot TCGA-WX-AA47-10A-01D-A38X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ee02016-ac11-42e3-94d5-0d5f36d11cac

The open-access MAF lists 41 somatic variants for this specimen: 33 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 7, Nonsense Mutation 3, Splice Site 1, Frame Shift Ins 1, In Frame Del 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.133T>C p.S45P | Missense Mutation (SNP) | VAF 64/139 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs121913407, COSV62687880, COSV62689248, COSV62696859; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANOS1 | c.1517G>A p.R506Q | Missense Mutation (SNP) | VAF 81/202 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.086); catalogued as rs1239045660, COSV52920657; called by muse, mutect2, varscan2
- ATG9A | c.1954C>G p.L652V | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.952); catalogued as COSV99522301; called by muse, mutect2, varscan2
- CCDC121 | c.736A>T p.R246* | Nonsense Mutation (SNP) | VAF 32/72 reads (44%) | catalogued as COSV99270536; called by muse, mutect2, varscan2
- CDK9 | c.449T>C p.M150T | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100953719; called by muse, mutect2, varscan2
- CENPE | c.5015A>G p.Q1672R | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV54383206; called by muse, mutect2, varscan2
- CFP | c.1390C>A p.P464T | Missense Mutation (SNP) | VAF 57/133 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99901692; called by muse, mutect2, varscan2
- CHD8 | c.7493A>C p.H2498P (on ENST00000646647 / NM_001170629.2; = p.H2219P on NM_020920.4) | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.924); catalogued as rs1174920611, COSV53522046; ClinVar: likely benign; called by muse, mutect2, varscan2
- CLK1 | c.71G>C p.S24T | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.046); catalogued as COSV100362468; called by muse, mutect2, varscan2
- COL24A1 | c.4927A>T p.K1643* | Nonsense Mutation (SNP) | VAF 71/188 reads (38%) | catalogued as COSV100994030; called by muse, mutect2, varscan2
- CSMD2 | c.1873G>C p.V625L | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.171); catalogued as rs767876663, COSV99590283, COSV99595753; called by muse, mutect2, varscan2
- EDN3 | c.631C>T p.H211Y (on ENST00000337938 / NM_001302455.2; = p.H197Y on NM_207033.3) | Missense Mutation (SNP) | VAF 55/118 reads (47%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.176); catalogued as COSV100285129; called by muse, mutect2, varscan2
- FRMPD1 | c.4148C>A p.A1383D | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.296); catalogued as COSV100899640; called by muse, mutect2, varscan2
- FZD1 | c.1648A>G p.I550V | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.4); PolyPhen benign (0.401); catalogued as rs753725473, COSV99842787; called by muse, mutect2, varscan2
- IL6ST | c.567_578del p.Y190_N193del | In Frame Del (DEL) | VAF 108/230 reads (47%) | catalogued as COSV61139872; called by mutect2, pindel, varscan2
- KANK1 | c.2569T>G p.S857A | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as COSV100620112; called by muse, mutect2, varscan2
- MAP3K21 | c.1129A>G p.M377V | Missense Mutation (SNP) | VAF 73/122 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); catalogued as rs1327714176, COSV100786321; called by muse, mutect2, varscan2
- NRROS | c.1118A>G p.E373G | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.265); catalogued as COSV100145638; called by muse, mutect2, varscan2
- OR1M1 | c.791C>T p.S264L | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.687); catalogued as rs1332959232, COSV101447568, COSV101447600; called by muse, mutect2
- PLXNB2 | c.4137G>C p.Q1379H | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV100834332; called by muse, mutect2, varscan2
- RPS13 | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 103/220 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs1324934975, COSV57179845; called by muse, mutect2
- RXRB | c.1570G>T p.E524* | Nonsense Mutation (SNP) | VAF 32/63 reads (51%) | catalogued as COSV100554576; called by muse, mutect2, varscan2
- SCN10A | c.1433G>T p.R478L | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV101479545, COSV71861011; called by muse, mutect2, varscan2
- SENP5 | c.352A>G p.K118E | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV100052300; called by muse, mutect2, varscan2
- TRIM11 | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99489040; called by muse, mutect2
- UGT2B10 | c.1579A>G p.R527G | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV55319428, COSV55323873; called by muse, mutect2
- YY1AP1 | c.794C>G p.P265R (on ENST00000295566 / NM_139118.2; = p.P188R on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as rs773985151, COSV99804755; called by muse, mutect2, varscan2
- ZFP90 | c.1716G>C p.E572D | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as COSV101238826; called by muse, mutect2, varscan2
- ZNF202 | c.854A>T p.D285V | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as COSV100279169; called by muse, mutect2, varscan2
- ZSCAN4 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV99990371; called by muse, mutect2, varscan2
- BASP1 | c.80_87dup p.A30Rfs*197 | Frame Shift Ins (INS) | VAF 77/326 reads (24%) | called by mutect2, varscan2
- CDKL4 | c.290+1del p.X97_splice | Splice Site (DEL) | VAF 23/76 reads (30%) | called by mutect2, pindel, varscan2
- STARD8 | c.1123_1130del p.W375Gfs*2 | Frame Shift Del (DEL) | VAF 63/178 reads (35%) | called by mutect2, pindel, varscan2
- ANKRD35 | c.2160C>T p.S720= | Silent (SNP) | VAF 48/174 reads (28%) | catalogued as rs1442136404, COSV100841866; called by muse, mutect2, varscan2
- ARL10 | c.576C>T p.A192= | Silent (SNP) | VAF 8/154 reads (5%) | catalogued as COSV100119148; called by muse, mutect2
- CELSR1 | c.2172C>T p.L724= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as COSV99420147; called by muse, mutect2, varscan2
- CWH43 | c.813A>G p.S271= | Silent (SNP) | VAF 28/65 reads (43%) | catalogued as COSV99894192; called by muse, mutect2, varscan2
- FBLN1 | c.1032C>T p.G344= | Silent (SNP) | VAF 38/102 reads (37%) | catalogued as rs1215978822, COSV99411561; called by muse, mutect2, varscan2
- SIX5 | c.1131C>T p.A377= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as rs772387291, COSV99353709; called by muse, mutect2, varscan2
- TTC14 | c.2312A>G p.*771= | Silent (SNP) | VAF 63/127 reads (50%) | catalogued as rs1375820099, COSV99870747; called by muse, mutect2, varscan2
- FARP1 | c.171+31294dup | Intron (INS) | VAF 21/74 reads (28%) | called by mutect2, pindel, varscan2
